Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A179, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A179-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Uterus, hysterectomy: High grade serous carcinoma is identified forming a mass (7.0 x 4.1 x 0.4 cm) circumferentially involving the endometrial cavity. The tumor invades 0.4 cm into the myometrium (total myometrial thickness, 1.6 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is identified. The margins are negative for tumor.
- B. Lymph nodes, right and left para-aortic, lymphadenectomy: Multiple (6 of 9) lymph nodes positive for metastatic carcinoma, consistent with endometrial primary.
- C. Ovary and fallopian tube, right, salpingo-oophorectomy: High grade serous carcinoma forming an intraluminal cystic mass involving the right fallopian tube. The right ovary is atrophic.
- D. Ovary and fallopian tube, left, salpingo-oophorectomy: High grade serous carcinoma involving the adnexal soft tissue and atrophic ovary. The left fallopian tube is unremarkable.
- E. Lymph nodes, right and left pelvic, lymphadenectomy: Multiple (2 of 21) lymph nodes are positive for metastatic carcinoma, consistent with endometrial primary.
- F. Omentum, omentectomy: Negative for tumor.

With available surgical materials, [AJCC (7th edition) pT3aN2].

[page 2 of 4]
PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, hysterectomy: Serous carcinoma. The margins are negative for tumor.

C. Ovary and fallopian tube, right, salpingo-oophorectomy:

Carcinoma involving the right fallopian tube. The right ovary is atrophic.

D. Ovary and fallopian tube, left, salpingo-oophorectomy: Carcinoma involving the adnexal soft tissue and ovary. The left fallopian tube is unremarkable.

F. Omentum, omentectomy: Negative for tumor.

HOLD to process lymph nodes on permanent sections.

Frozen section histologic interpretation performed by:

GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 123.0 gram uterus with an unremarkable cervix. The uterine serosa is smooth. There is a 7.0 x 4.1 x 1.1 cm mass involving the entire endometrial cavity and lower uterine segment which grossly appears to invade 0.2 cm into the 1.6 cm thick myometrium. Representative sections are submitted.

B. Received fresh labeled "right and left para-aortic nodes" is a 5.4 x 4.5 x 1.9 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

[page 3 of 4]
C. Received fresh labeled "right tube and ovary" is a 2.0 x 1.4 x

0.6 cm ovary with an 8.0 x 0.6 cm attached fallopian tube with a 1.0

x 0.8 cm paratubal cyst. The ovary has a smooth outer surface and a

solid cut surface. Representative sections submitted.

D. Received fresh labeled "left tube and ovary" is a 2.5 x 1.2 x

0.7 cm ovary with a 7.0 x 0.4 cm attached fallopian tube. The ovary

has a smooth outer surface and a solid cut surface.

Representative sections submitted.

E. Received fresh labeled "right and left pelvic lymph nodes" is a

9.8 x 7.4 x 1.2 cm aggregate of adipose tissue and lymph nodes. All

lymph nodes submitted.

F. Received fresh labeled "dependent omentum" is a 17.2 x 13.0 x

1.5 cm portion of omentum. No masses are identified grossly. Lymph

nodes are not identified. Representative sections submitted.

BLOCK SUMMARY:

Part A: Uterus

- 1 Endometrial tumor
- 2 Cervix
- 3 Endocervix
- 4 Endometrial tumor-2
- 5 Endometrial tumor-3
- 6 Endometrial tumor-4
- 7 Endometrial tumor-5

Part B: Right and left para aortic lymph nodes

- 1 Rt/Lt paraaortic LN 2(B1)
- 2 Rt/Lt paraaortic LN 1(B2)
- 3 Rt/Lt paraaortic LN 2(B3)
- 4 Rt/Lt paraaortic fat-1
- 5 Rt/Lt paraaortic fat-2
- 6 Rt/Lt paraaortic LN 1(B4)

Part C: Right tube and ovary

- 1 Right fallopian tube

[page 4 of 4]
2 Right ovary

Part D: Left tube and ovary

- 1 Left fallopian tube
- 2 Left ovary
- 3 Left adnexal tissue

Part E: Right & left pelvic Lymph Nodes

- 1 Pelvic LNs-5(E1)
- 2 Pelvic LNs-2(E2)
- 3 Pelvic LNs-5(E3)
- 4 Pelvic LNs-2(E4)
- 5 Pelvic LNs-3(E5)
- 6 Pelvic LNs-2(E6)
- 7 Pelvic LN-1(E7)
- 8 Pelvic LN-1(E8)
- 9 Pelvic LNs-2(E9)
- 10 Pelvic LNs-4(E10)
- 11 Pelvic LN-1(E11)

Part F: Dependent Omentum

- 1 Dependent omentum

Source: NCI Genomic Data Commons file 6faed88b-3a6a-4edc-8f13-8563f9f5e731 (TCGA-D1-A179.F8F4C024-B723-424C-B98D-AA885C38CDFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).